Somatic mutation profile of tumor specimen C3L-01557-01 (aliquot CPT0085670009) from CPTAC case C3L-01557, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 51.1 years (18,652 days).
Specimen C3L-01557-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a32b96e-e23f-4633-baf6-3db7af79094e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01557-31 (Blood Derived Normal), aliquot CPT0086610002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d11f8dfb-7515-4ad6-8331-8babac81aecb

The open-access MAF lists 58 somatic variants for this specimen: 41 protein-altering or splice-affecting, 8 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 8, Intron 7, Frame Shift Del 3, Splice Site 1, Nonsense Mutation 1, Frame Shift Ins 1, In Frame Del 1, 3'UTR 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFTR | c.2997_3000del p.I1000* | Frame Shift Del (DEL) | VAF 178/433 reads (41%) | catalogued as rs397508472; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.380C>A p.S127Y | Missense Mutation (SNP) | VAF 32/200 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52666031, COSV52675881, COSV52731113, COSV52828604; called by muse, mutect2, varscan2
- VHL | c.341-2A>G p.X114_splice | Splice Site (SNP) | VAF 86/278 reads (31%) | hotspot (GDC flag); catalogued as rs869025637, CS071275, COSV56542830, COSV56544966, COSV56548666, COSV56554645; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRINP2 | c.1996C>G p.L666V | Missense Mutation (SNP) | VAF 49/355 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.142); catalogued as COSV64179749; called by muse, mutect2, varscan2
- EPRS1 | c.2770C>G p.P924A | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1051521545; called by muse, mutect2, varscan2
- INTS5 | c.1731del p.L578Wfs*4 | Frame Shift Del (DEL) | VAF 39/155 reads (25%) | catalogued as COSV57953373; called by mutect2, pindel, varscan2
- IQSEC2 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.08); catalogued as rs1556879969; called by muse, mutect2
- KCNH5 | c.1927C>T p.R643W | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs771984476; called by muse, mutect2, varscan2
- NCAPH | c.706G>C p.D236H | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV53637453; called by muse, mutect2, varscan2
- NRXN1 | c.1142G>A p.G381D | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100455337; called by muse, mutect2, varscan2
- PBRM1 | c.286A>T p.K96* | Nonsense Mutation (SNP) | VAF 40/91 reads (44%) | catalogued as COSV56284913, COSV56297688; called by muse, mutect2, varscan2
- PCBP3 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.8); catalogued as rs745636178, COSV68407473; called by muse, mutect2, varscan2
- RNF14 | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs138098478; called by muse, varscan2
- RNF213 | c.12482C>G p.A4161G | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.433); catalogued as COSV60408699; called by muse, mutect2, varscan2
- SEC24A | c.926G>T p.G309V | Missense Mutation (SNP) | VAF 22/243 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV100524711; called by muse, mutect2
- AUTS2 | c.2459C>A p.S820Y | Missense Mutation (SNP) | VAF 70/346 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- BCAR3 | c.563T>C p.L188P | Missense Mutation (SNP) | VAF 89/291 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C6orf136 | c.895del p.A299Pfs*11 (on ENST00000376473 / NM_001109938.3; = p.A165Pfs*11 on NM_145029.4) | Frame Shift Del (DEL) | VAF 82/364 reads (23%) | called by mutect2, pindel, varscan2
- CC2D1A | c.839C>T p.T280I | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CENPT | c.773T>C p.L258P | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- COL2A1 | c.1474G>C p.G492R | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DEPDC1B | c.693dup p.L232Sfs*2 | Frame Shift Ins (INS) | VAF 18/101 reads (18%) | called by mutect2, pindel, varscan2
- EHMT2 | c.3437C>A p.T1146N | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ENOSF1 | c.679+3G>A | Splice Region (SNP) | VAF 29/127 reads (23%) | called by muse, mutect2, varscan2
- GBF1 | c.4727A>T p.H1576L (on ENST00000369983 / NM_001377137.1; = p.H1575L on NM_004193.3) | Missense Mutation (SNP) | VAF 52/237 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- GPR157 | c.523A>G p.K175E | Missense Mutation (SNP) | VAF 133/528 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KREMEN1 | c.371A>T p.K124M (on ENST00000407188; = p.K126M on NM_032045.5) | Missense Mutation (SNP) | VAF 93/308 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- MKI67 | c.5500G>A p.G1834S | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCAPG2 | c.1429G>C p.V477L | Missense Mutation (SNP) | VAF 83/373 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- NCAPG2 | c.112_114del p.L39del | In Frame Del (DEL) | VAF 99/225 reads (44%) | called by mutect2, pindel, varscan2
- OPTN | c.1676G>T p.G559V | Missense Mutation (SNP) | VAF 159/585 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- PDCD2 | c.671A>G p.E224G | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- PIKFYVE | c.5098C>T p.L1700F | Missense Mutation (SNP) | VAF 68/291 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- PTPRC | c.3062C>A p.S1021Y | Missense Mutation (SNP) | VAF 124/326 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RANBP2 | c.2840A>G p.E947G | Missense Mutation (SNP) | VAF 131/449 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- SCUBE3 | c.2588T>A p.M863K | Missense Mutation (SNP) | VAF 81/240 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SLC1A2 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC27A3 | c.2002T>C p.F668L (on ENST00000271857; = p.F540L on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 186/433 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SP100 | c.2320G>C p.E774Q | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- TBC1D23 | c.17A>C p.D6A | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZMIZ1 | c.1174G>T p.G392C | Missense Mutation (SNP) | VAF 32/221 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- AHCTF1 | c.6735T>C p.A2245= (on ENST00000366508; = p.A2219= on NM_015446.5) | Silent (SNP) | VAF 70/197 reads (36%) | catalogued as rs376646297; called by muse, mutect2, varscan2
- CACNA1D | c.6255A>G p.K2085= (on ENST00000350061 / NM_001128840.3; = p.K2105= on NM_000720.4) | Silent (SNP) | VAF 52/147 reads (35%) | called by muse, mutect2, varscan2
- FANCI | c.3216T>C p.F1072= (on ENST00000310775 / NM_001376911.1; = p.F1012= on NM_018193.3) | Silent (SNP) | VAF 167/649 reads (26%) | catalogued as rs1001373376; called by muse, mutect2, varscan2
- FSTL4 | c.60G>A p.A20= | Silent (SNP) | VAF 78/385 reads (20%) | catalogued as rs760231160, COSV54765038; called by muse, mutect2, varscan2
- KRT8 | c.414C>T p.N138= | Silent (SNP) | VAF 120/460 reads (26%) | catalogued as rs765627448; called by muse, varscan2
- NR3C2 | c.1941T>C p.I647= | Silent (SNP) | VAF 66/240 reads (28%) | called by muse, mutect2, varscan2
- THSD7A | c.1687C>T p.L563= | Silent (SNP) | VAF 68/235 reads (29%) | called by muse, mutect2, varscan2
- TYR | c.465C>T p.T155= | Silent (SNP) | VAF 157/549 reads (29%) | catalogued as COSV54483606; called by muse, varscan2
- GSN | c.1039+14G>C | Intron (SNP) | VAF 116/409 reads (28%) | called by muse, mutect2, varscan2
- HGSNAT | c.1013-1640G>A | Intron (SNP) | VAF 4/24 reads (17%) | catalogued as rs368341838; called by muse, varscan2
- HNF1A | c.1501+98A>T | Intron (SNP) | VAF 67/265 reads (25%) | called by muse, mutect2, varscan2
- LIMA1 | c.1141-3408C>G | Intron (SNP) | VAF 14/287 reads (5%) | called by muse, mutect2
- SNRNP200 | c.4916-43G>A | Intron (SNP) | VAF 53/222 reads (24%) | catalogued as rs753209497, COSV60488645; called by muse, mutect2, varscan2
- SPAG8 | c.*854C>T | 3'UTR (SNP) | VAF 22/243 reads (9%) | catalogued as rs1264860622, COSV52413685; called by muse, mutect2
- SYT1 | c.352-179G>A | Intron (SNP) | VAF 30/142 reads (21%) | catalogued as rs1447842653, COSV54047074; called by muse, mutect2, varscan2
- TRIM47 | c.1202-12C>T | Intron (SNP) | VAF 73/244 reads (30%) | called by muse, mutect2, varscan2
- XIST | n.10304T>A | RNA (SNP) | VAF 99/187 reads (53%) | called by muse, mutect2, varscan2
